Surgical pathology report (de-identified scan), TCGA case TCGA-J8-A3YF, project TCGA-THCA (Thyroid Carcinoma), tissue source site Mayo Clinic, specimen TCGA-J8-A3YF-01A (Primary Tumor).

[page 1 of 3]
**SurgPath Final
Temporary Copy**

Page 1 of 3

FINAL DIAGNOSIS

A) Lymph nodes, right neck contents, excision: Metastatic papillary thyroid carcinoma involving one (of 12) lymph nodes.

B) Lymph nodes, right paratracheal, excision: Two benign lymph nodes and portion of parathyroid gland identified.

C, D) Thyroid, right and left lobes and isthmus, resection: Multifocal papillary thyroid carcinoma identified in the left and right thyroid lobes (up to 0.5 cm); no extrathyroidal extension is identified and the margins are negative for tumor. In addition, the thyroid shows nodular hyperplasia and marked changes of chronic lymphocytic (Hashimoto's) thyroiditis. Five perithyroidal lymph nodes are benign. See synoptic findings below.

E) Lymph nodes, central compartment, excision: Two benign lymph nodes.

D: Thyroid Gland
HISTOLOGIC TYPE:
Papillary carcinoma

ICD-O-3
Carcinoma, papillary, thyroid
8260/3

TUMOR SITE:
Right Lobe
Left Lobe

Site: thyroid, NOS
C73.9

TUMOR SIZE:
Greatest Dimension: 0.5 cm

6-7-12
RD

PRIMARY TUMOR (pT):
pT1: Tumor size 2 cm or less, limited to thyroid

REGIONAL LYMPH NODES (pN):
pN1b: Metastases to unilateral, bilateral or contralateral cervical or superior mediastinal lymph nodes

NUMBER OF LYMPH NODE(S) INVOLVED: 1

NUMBER OF LYMPH NODE(S) EXAMINED: 21

DISTANT METASTASIS (pM):

[page 2 of 3]
pMX: Cannot be assessed

MARGINS:

Margins uninvolved by carcinoma

ADDITIONAL PATHOLOGIC FINDINGS:

Other: Chronic lymphocytic (Hashimoto's) thyroiditis and nodular hyperplasia.

SPECIMEN RECEIVED

- A) RIGHT NECK CONTENTS
- B) RIGHT PARATRACHEAL LYMPH NODES
- C) RIGHT THYROID LOBE AND ISTHMUS
- D) LEFT THYROID LOBE
- E) CENTRAL COMPARTMENT

GROSS DESCRIPTION

A) Received fresh labeled "right neck contents" is an unoriented portion of red/tan to yellow soft tissue measuring approximately 10.5 x 7.0 x 1.5 cm. The specimen is dissected, revealing a gray/yellow to yellow/tan, necrotic-appearing mass measuring approximately 2.7 cm in greatest dimension. The mass also appears focally calcified. A portion of this mass is collected for the

Sectioning through the remainder of the specimen reveals 18 lymph node candidates measuring up to 0.9 cm in greatest dimension. Representative sections are submitted as follows: Mass A1-A3, and lymph node candidates A4-A7. Sections are decalcified, as needed.

B) Received fresh labeled "right paratracheal lymph nodes" is a portion of node-bearing adipose tissue measuring approximately 1.5 x 1.5 x 0.7 cm. Dissection yields four possible lymph nodes measuring up to 0.7 cm in greatest dimension. These are entirely submitted as B1.

C) Received fresh labeled "right thyroid lobe and isthmus" is a 21-gram lobe of thyroid and isthmus. The right lobe measures approximately 6.5 x 3.0 x 1.8 cm, while the isthmus measures approximately 3.5 x 1.8 x 1.1 cm. The capsule grossly appears intact. The specimen is inked on its surgical margins. Sectioning reveals

[page 3 of 3]
an indurated grey/tan nodule in the isthmus measuring 0.6 cm in greatest dimension. Within the right lobe, there is a well-circumscribed pink/tan to pink/red nodule present measuring 1.6 cm in greatest dimension. This lies in the inferior pole. In the superior pole, there is a smaller nodule measuring 0.8 cm in greatest dimension. Lateral to the lobe, there is an adherent nodule weighing approximately 20 mg and measuring 0.7 cm in greatest dimension. Representative sections are submitted as follows: Isthmus nodule C1, random Isthmus C2, largest right lobe nodule in its entirety C3-C5, smaller right lobe nodule C6, random right lobe C7-C8, and nodule lateral to right lobe C9. The remainder of the specimen is subsequently submitted as C10-C17.

D) Received fresh labeled "left thyroid lobe" is a 21-gram lobe of thyroid measuring approximately 6.5 x 3.8 x 1.8 cm. The capsule grossly appears intact. The specimen is inked on its surgical margins. Sectioning reveals one well-circumscribed tan to red/tan nodule measuring 1.5 cm in greatest dimension. The remainder of the thyroid appears grossly unremarkable. Representative sections are submitted as follows: Entire nodule D1-D2 and random thyroid D3-D6.

E) Received fresh labeled "central compartment" are two portions of node-bearing adipose tissue aggregating to approximately 3.0 x 2.0 x 0.8 cm. Dissection yields three possible lymph nodes measuring up to 0.5 cm in greatest dimension. These are entirely submitted as E1.

CLINICAL INFORMATION
PAPILLARY THYROID CARCINOMA

5/24/12

Source: NCI Genomic Data Commons file 2e84f926-8052-48b0-912b-b78dfd37f2a8 (TCGA-J8-A3YF.5098FC1F-A851-413D-80CA-FF512E458B26.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).